Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4974, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4974-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

with left renal mass.

TCGA - BP - 4974

Specimens Submitted:

1: SP: Left kidney; nephrectomy;

DIAGNOSIS:

1. SP: Left kidney; nephrectomy;

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 5.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not Identified

Lymph Nodes:

Number of metastatic nodes:0

Number of nodes examined:3

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1).The specimen is received fresh labeled "Left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 220 g in total. The kidney measures 14 x 6.0 x 5.0 cm. The attached ureter measures 4.0 cm in length and 0.4 cm in diameter. The attached renal vein measures 0.9 cm in length and 1.0 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a well-circumscribed, round, hemorrhagic bright orange tumor measuring 5.5 x 5.5 x 5.0 cm. The tumor is located in the cortex of the lower pole. Pelvis is not grossly involved by tumor. The tumor impinges on the renal vein and sinus fat, but does not show any gross invasion and does not extend through the capsule of the kidney. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 2.0 cm and the calyces appear normal. on complete opening of the ureter, renal pelvis, and collecting ducts, they show grossly unremarkable white-tan mucosa. Several lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections.the specimen is photographed.

Summary of sections:

UM -- ureteral and vessel margins

VM-vessel margins

PNF-- tumor with perinephric fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

TV-tumor with adjacent vessel

FUP-fat, upper pole

RS -- representative sections kidney

LN-lymph nodes

TPVF- Tumor to peripelvic fat

Summary of Sections:

Part 1: SP: Left kidney; nephrectomy;

Block	Sect. Site	PCs
1	fup	1
1	ln	1
2	pnf	2
1	rs	1
2	tk	2
1	tpvf	1
2	tv	2
1	um	1
1	vm	1

Source: NCI Genomic Data Commons file 95cb25e0-8209-4e2f-9b34-495c6e0831b3 (TCGA-BP-4974.01388CAC-9613-45A4-95E5-6BFFAC67EF16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).